Surgical pathology report (de-identified scan), TCGA case TCGA-E1-A7YV, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-A7YV-01A (Primary Tumor).

[page 1 of 4]
Patient

Surgical Pathology: Additional Info

Surg Path

CLINICAL HISTORY:

Brain tumor.

GROSS EXAMINATION:

A. "Brain tissue", received fresh for frozen section and placed in formalin on
at is a 6.8 x 6.5 x 1.4 cm tan-white to tan-yellow focally
hemorrhagic portion of brain. A representative section is submitted for
frozen section as AF1. The frozen section remnant is submitted in A1. The
remaining brain tissue exhibits a tan-yellow cut surface with focal
hemorrhage. Additional representative sections submitted in A2-4.

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue":AF1 -anaplastic glioma most consistent with
oligodendroglioma (Dr.

MICROSCOPIC EXAMINATION:

Microscopic examination shows brain infiltrated by a glial neoplasm
characterized by hypercellularity, mitoses and microvascular changes. No
necrosis is seen. In some areas the tumor cells are hyperchromatic and
exhibit increased cytological pleomorphism. In other areas the tumor cells
have an oligodendroglioma appearance including cytoplasmic clearing,
perineuronal and perivascular satellitosis. The tumor cells are
immunopositive for GFAP. HAM-56 highlights blood vessels. The MIB-1 index is
approximately 30%.

IMMUNOHISTOCHEMICAL FINDINGS:

The immunoperoxidase tests reported herein were developed and their
performance characteristics were determined by the

Some of them may not be cleared or approved by
the U.S. Food and Drug Administration. The FDA has determined that such
clearance or approval is not necessary. These tests are used for clinical
purposes. They should not be regarded as investigational or for research.
This laboratory is certified under the Clinical Laboratory Improvement
Amendments of 1988 (CLIA) as qualified to perform high complexity clinical
testing.

DIAGNOSIS:

A. BRAIN TISSUE, CRANIOTOMY:

ANAPLASTIC OLIGOASTROCYTOMA (WHO GRADE III).

200-0-3 9302/3
Oligoastrocytoma, grade III
Site: supratentorial NOS C71.0
with Brain NOS C71.9
9/25/14

I certify that I personally conducted the diagnostic evaluation of the above
specimen(s) and have rendered the above diagnosis(es).

M.D.

Electronically signed:

ADDENDUM 1:

Please see Image Cytometry Report for results of supplementary
tests.

FISH INTERPRETATION SUMMARY:

FISH MARKER	INTERPRETATION	% OF TUMOR CELLS	FINDINGS/STATUS
-------------	----------------	------------------	-----------------

[page 2 of 4]
EXHIBITING ABNORMALITY

EGFR (7p12)	ABNORMAL	84%	GAIN
MET (7q31)	ABNORMAL	76%	GAIN
7 CEP	ABNORMAL	83%	GAIN
KIT (4q12)	ABNORMAL	53%	GAIN
CEP 4	ABNORMAL	50%	GAIN
PTEN (10q23)	NORMAL	60%	GAIN
10 CEP	NORMAL	54%	GAIN
CDKN2A (9p21)	NORMAL	67%	GAIN
CEP 9	NORMAL	62%	GAIN
1p36 (EGFL3)	NORMAL	62%	GAIN
1q25 (ANGPTL1)	CONTROL INTACT		
1p32 (BAC-260123)	NORMAL	60%	GAIN
1qtel (D1S3738)	CONTROL INTACT		
19q13 (GLTSCR)	NORMAL	58%	GAIN
19p13 (ZNF44)	CONTROL INTACT		

EGFR, 7 CEP, PTEN, 10 CEP: 2 OF 4 ABNORMAL MARKERS.

MET, KIT, AND 9p21 EXHIBIT POLYSPMY.

COMMENT: SEQUENCING FOR P53 MUTATIONS WILL BE ORDERED REFLEXIVELY AND REPORTED AS AN ADDENDUM.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

M.D.

Electronically signed [REDACTED]

ADDENDUM 2:

BRAIN TISSUE CONTAINING ANAPLASTIC OLIGOASTROCYTOMA (WHO GRADE III;

IHC Antibody:	Interpretatin IHC	Score (0-3+)	% of Tumor Cells of Exhibiting Staining	ACIS III SCORE
CD/45-LCA			5%	
Ki-67	NOT ORDERED			
MGMT	POSITIVE		20%	20%
EGFR wt	POSITIVE	2+	60%	
EGFR VIII	NEGATIVE		0%	0%
PTEN	NOT ORDERED			
pS6	NEGATIVE	2+	5%	
PAKT	NEGATIVE	2+	5%	
pMAPK	NEGATIVE	2+	5%	
CA-IX	POSITIVE		5%	
VEGF	POSITIVE	2+	60%	= 120
PDGFr alpha	WIDESPREAD		60%	

[page 3 of 4]
PDGFr Beta	WIDESPREAD		60%
VEGFr-KDR	POSITIVE	2+	10% = 20
HIF2 alpha:	NOT ORDERED		

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

M.D.

Electronically signed: [REDACTED]

ADDENDUM 3:

MGMT PROMOTER METHYLATION REAL TIME PCR ANALYSIS

Received [REDACTED] from

is a copy of an MGMT Promoter Methylation Assay, obtained at the request of Dr. [REDACTED] on paraffin block [REDACTED]. The complete report from [REDACTED] is on file in the [REDACTED]

Result:

MGMT PROMOTER METHYLATION IDENTIFIED

Methodology:

DNA is isolated from formalin-fixed, paraffin-embedded (FFPE) specimen. Molecular analysis of the MGMT gene is performed by methylation-specific PCR. Molecular-based testing is highly accurate but as in any laboratory test, rare diagnostic errors may occur.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

M.D.

Electronically signed: [REDACTED]

ADDENDUM 4:

Please see MOLECULAR DIAGNOSTICS Report [REDACTED] for complete report.

Testing was performed on sample [REDACTED] BLOCK [REDACTED]

IDH1 MUTATION TESTING WITH REFLEX TO IDH2

INTERPRETATION: POSITIVE.

IDH1 MUTATION DETECTED.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

M.D.

Electronically signed: [REDACTED]

ADDENDUM 5:

EGFR vIII IMMUNOHISTOCHEMISTRY: NEGATIVE

[page 4 of 4]
None of the tumor cells exhibit staining for EGFR VIII (Score = 0).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

M.D.

Performed by: Electronically signed: [REDACTED]
SURGICAL PATHOLOGY

Ordering MD:

Source: NCI Genomic Data Commons file 73c6790e-80e7-4cfa-b488-c5395b9c537f (TCGA-E1-A7YV.96974491-20AD-491B-A475-80DB896312C8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).